TCGA case TCGA-W5-AA2M — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bec2cf62-44a2-42e5-8e10-440aad69ed77

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 540 days (1.5 years).

Diagnoses (2)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C24.0; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 49.3 years (17,989 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Peritoneum, NOS. Age at diagnosis: 49.7 years (18,146 days); Days to diagnosis: 157 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 157 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 157 days.
- Days to follow up: 540 days (1.5 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 138 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 40.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Platelets 355 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 1.1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Alpha Fetoprotein 4.5 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 1 mg/dL [Blood test normal range lower: 0.9; Blood test normal range upper: 1.4].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 180 cm; BMI: 24.4.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA2M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-W5-AA2M-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-W5-AA2M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, hilar/perihilar; Surgical procedure other: lobectomy and extrahepatic bile duct regional lymphadenectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 540 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 540 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 157 days.
